Somatic mutation profile of tumor specimen TCGA-EL-A4JX-01A (aliquot TCGA-EL-A4JX-01A-12D-A257-08) from TCGA case TCGA-EL-A4JX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.4 years (11,465 days).
Specimen TCGA-EL-A4JX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0652659f-c722-4f76-99b3-c9fe0c1cf5e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4JX-11A (Solid Tissue Normal), aliquot TCGA-EL-A4JX-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59f67b6f-8c09-4fb7-8beb-4c9c70cb183e

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GPAT4 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1460211123, COSV101213793; called by muse, mutect2, varscan2
- GPR101 | c.1458C>A p.D486E | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV53239464; called by muse, mutect2, varscan2
- GPR4 | c.470A>T p.E157V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV59917542; called by muse, mutect2, varscan2
- KRT9 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs767325538, COSV55854102; called by mutect2, varscan2
- PELI1 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV62730330; called by muse, mutect2
- TNNT3 | c.693G>C p.K231N (on ENST00000397301 / NM_001367846.1; = p.K220N on NM_006757.4) | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV53487803; called by muse, mutect2, varscan2
- SYF2 | c.465_467+1delinsT p.X155_splice | Splice Site (DEL) | VAF 14/104 reads (13%) | called by pindel, varscan2*
- GPAT4 | c.873G>A p.E291= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101214030, COSV67841141; called by muse, mutect2, varscan2
- MAN1A1 | c.969T>G p.P323= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1235690271, COSV63783417; called by muse, mutect2, varscan2
- PHKA2 | c.3324G>A p.S1108= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as rs1212125323, COSV66054925; called by muse, mutect2, varscan2
